Gene-level copy-number profile of tumor specimen TCGA-D5-6929-01A from TCGA case TCGA-D5-6929, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 49.1 years (17,919 days).
Specimen TCGA-D5-6929-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.dcb88804-cc6f-41b3-9c20-2fa29cf47293.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D5-6929-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c180dbfc-253a-4a64-9e6a-151c3c49c98a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 819; copy number 4: 28,524; copy number 5: 372; copy number 6: 21,628; copy number 7: 204; copy number 8: 6,112; copy number 9: 919; copy number 10: 728; copy number 11: 454; copy number 12: 60.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D5-6929-01A-31D-1923-01): tumor purity 0.48, ploidy 2.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,161 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–32,224,379, 550 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr6:60,719,222–67,467,308, 45 genes, copy number 9: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208.
- chr6:103,583,135–107,133,170, 49 genes, copy number 9: AL591387.1, AL590608.1, R3HDM2P2, NPM1P10, AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P.
- chr6:107,192,300–107,230,152, 2 genes, copy number 9: AL591516.1, RPS24P12.
- chr6:154,010,496–155,257,723, 19 genes, copy number 9 (within-gene range 6–9): OPRM1, IPCEF1, AL357075.4, AL445220.1, CNKSR3, AL357075.2, AL357075.3, AL357075.1, MTRES1P1, RPS4XP8, AL591419.1, AL591499.1, SCAF8, RNU6-824P, TIAM2, AL121952.1, MIR1273C, U8, AL136228.1.
- chr7:81,489,204–95,615,132, 169 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr12:16,661,766–19,376,400, 29 genes, copy number 9: AC007529.2, AC007529.1, SKP1P2, EEF1A1P16, AC092793.1, RNU6-837P, AC092110.1, RPL7P40, PSMC1P8, TIMM17BP1, AC048352.1, LINC02378, MIR3974, Y_RNA, RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P.
- chr12:51,590,266–53,102,345, 82 genes, copy number 9 (broad region; genes not listed).
- chr15:25,848,747–26,477,840, 10 genes, copy number 10: MIR4715, AC016266.1, LINC02346, AC044913.2, AC044913.1, AC100836.1, LINC00929, AC012060.1, LINC02248, AC009878.2.
- chr15:26,557,598–26,557,937, 1 gene, copy number 10: AC009878.1.
- chr15:30,005,205–32,615,158, 94 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr17:33,935,437–34,156,000, 1 gene, copy number 10 (within-gene range 8–10): AC004147.4.
- chr17:34,036,681–41,865,423, 386 genes, copy number 9–12 (broad region; genes not listed).
- chr17:41,867,581–41,867,736, 1 gene, copy number 9: AC125257.2.
- chr17:60,177,327–69,355,218, 263 genes, copy number 9–10 (within-gene range 4–10) (broad region; genes not listed).
- chr17:69,433,084–69,435,533, 1 gene, copy number 10: AC015920.1.
- chr18:48,475,487–48,479,228, 3 genes, copy number 10: RNA5SP456, AC024288.1, POLR3GP2.
- chr18:49,739,823–49,813,953, 2 genes, copy number 9 (within-gene range 5–9): AC090227.3, ACAA2.
- chr20:30,278,906–45,948,023, 454 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
